Somatic mutation profile of tumor specimen MMRF_2183_1_BM_CD138pos (aliquot MMRF_2183_1_BM_CD138pos_T1_KHS5U_L11064) from MMRF case MMRF_2183, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.6 years (29,061 days).
Specimen MMRF_2183_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2e2a8b4-082b-4352-929d-c361759e468f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2183_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2183_2_PB_Whole_C1_KHS5U_L08774; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/033d495e-6db2-451d-85cc-c67c00faec79

The open-access MAF lists 135 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 36, Intron 16, Silent 16, 5'Flank 6, Nonsense Mutation 5, 3'Flank 4, 5'UTR 3, Splice Region 3, Frame Shift Del 2, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 58/144 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 12/152 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABLIM1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as rs1322528617, COSV53299667; called by muse, mutect2, varscan2
- ADAMTS9 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1049047605, COSV55776682; called by muse, mutect2
- ANXA6 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 105/162 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1177861653, COSV62905807; called by muse, mutect2, varscan2
- CAMKK2 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs374592351; called by muse, mutect2, varscan2
- CMYA5 | c.8627C>T p.A2876V | Missense Mutation (SNP) | VAF 82/386 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150027467; called by muse, mutect2, varscan2
- CRYBG2 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 155/405 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs373673197; called by muse, mutect2, varscan2
- CX3CL1 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as rs201467674, COSV50055436; called by muse, mutect2, varscan2
- DENND4C | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs536726285; called by muse, mutect2, varscan2
- ESRP1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 13/120 reads (11%) | catalogued as COSV100619704, COSV64409603; called by muse, mutect2, varscan2
- FLT4 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs748722317; called by muse, varscan2
- IGHD3-3 | c.5T>A p.L2* | Nonsense Mutation (SNP) | VAF 15/16 reads (94%) | catalogued as rs546100128; called by muse, mutect2, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGHV4-34 | c.172T>A p.Y58N | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs587643115; called by muse, mutect2, varscan2
- IRX2 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as rs747627856, COSV57409929; called by muse, mutect2, varscan2
- LBR | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772650538; called by muse, mutect2, varscan2
- MRC2 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs775158529; called by muse, mutect2
- MYO3B | c.3077C>A p.A1026D | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.281); catalogued as rs1202094369; called by muse, mutect2, varscan2
- NR5A2 | c.664G>A p.G222S (on ENST00000367362 / NM_205860.3; = p.G176S on NM_003822.5) | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99371358; called by muse, mutect2
- OTOGL | c.2517T>C p.A839= (on ENST00000547103; = p.A830= on NM_173591.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 13/125 reads (10%) | catalogued as COSV101509499; called by muse, mutect2, varscan2
- SLC24A4 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs552043382, COSV54119555; called by muse, mutect2, varscan2
- SLC4A9 | c.2764C>T p.R922* (on ENST00000507527 / NM_001258428.2; = p.R898* on NM_031467.3) | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV50186681; called by muse, mutect2, varscan2
- SLC6A2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1439637030, COSV54919847; called by muse, mutect2
- SYT9 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.019); catalogued as rs747985314; called by muse, varscan2
- TRIM47 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs138136962; called by muse, mutect2, varscan2
- TSC2 | c.2674G>A p.V892I | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs376801256, COSV54773672; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTK | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100036790; called by muse, mutect2
- VARS1 | c.3460G>A p.V1154M | Missense Mutation (SNP) | VAF 146/217 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs548042700; called by muse, mutect2, varscan2
- WSCD2 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.844); catalogued as rs770059284, COSV54578551; called by muse, mutect2, varscan2
- ZNF516 | c.2803G>A p.V935I | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs745729483; called by muse, mutect2, varscan2
- ACAN | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- ACP1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKFY1 | c.2818C>T p.Q940* (on ENST00000341657 / NM_001330063.2; = p.Q941* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- ATAD2 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- COL15A1 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- COL22A1 | c.2270C>A p.P757Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- EIF2AK3 | c.1108_1109insTA p.D370Vfs*7 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | called by mutect2, pindel*, varscan2
- ERVV-2 | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 107/444 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- F8 | c.1604C>G p.T535S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.148); called by mutect2, varscan2
- FAM107B | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FIP1L1 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 85/230 reads (37%) | called by muse, mutect2, varscan2
- GABRE | c.1137+7G>T | Splice Region (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- HINT3 | c.81del p.S28Qfs*44 | Frame Shift Del (DEL) | VAF 22/176 reads (13%) | called by mutect2, pindel, varscan2
- MAST4 | c.2671G>T p.D891Y (on ENST00000403625 / NM_001164664.2; = p.D702Y on NM_015183.3) | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEB | c.402+2T>A p.X134_splice | Splice Site (SNP) | VAF 34/408 reads (8%) | called by muse, mutect2
- NHS | c.2642A>G p.E881G | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USH2A | c.12071C>T p.T4024I | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- USP38 | c.2967+8G>A | Splice Region (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.654+2T>C p.X218_splice | Splice Site (SNP) | VAF 38/64 reads (59%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.3074del p.S1025Tfs*41 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | called by mutect2, pindel, varscan2
- AKAP6 | c.2802C>T p.S934= | Silent (SNP) | VAF 76/202 reads (38%) | catalogued as rs780876876; called by muse, mutect2, varscan2
- BAZ2B | c.2187A>G p.P729= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as rs774482298; called by muse, mutect2, varscan2
- GFRA1 | c.375C>T p.N125= | Silent (SNP) | VAF 19/256 reads (7%) | catalogued as COSV62610101; called by muse, mutect2
- GOLGA4 | c.4116T>G p.L1372= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- IGHV2-70 | c.357A>C p.I119= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs139383686; called by muse, varscan2
- IGHV2-70 | c.96A>G p.K32= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as rs368957766; called by muse, varscan2
- IGHV4-34 | c.282C>T p.T94= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as rs781082961; called by muse, mutect2, varscan2
- IGLV3-25 | c.90A>T p.S30= | Silent (SNP) | VAF 61/67 reads (91%) | catalogued as rs549661306; called by muse, varscan2
- IYD | c.778C>T p.L260= | Silent (SNP) | VAF 40/282 reads (14%) | called by muse, mutect2, varscan2
- IZUMO1R | c.21C>G p.L7= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV60623752; called by mutect2, varscan2
- MROH2B | c.594C>A p.A198= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV68186283; called by muse, mutect2, varscan2
- RNF103 | c.186G>A p.L62= | Silent (SNP) | VAF 78/222 reads (35%) | called by muse, mutect2, varscan2
- THSD1 | c.1761C>A p.I587= | Silent (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- TMEM245 | c.435C>G p.R145= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- TRIM58 | c.174G>A p.P58= | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- ZNF554 | c.1515A>C p.S505= | Silent (SNP) | VAF 79/320 reads (25%) | called by muse, mutect2, varscan2
- AC007557.3 | n.2161del | RNA (DEL) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- ACBD6 | chr1:180502858 A>C | 5'Flank (SNP) | VAF 113/243 reads (47%) | catalogued as rs116237153; called by muse, mutect2, varscan2
- ACTR3C | chr7:150245635 T>C | 3'Flank (SNP) | VAF 22/554 reads (4%) | called by muse, mutect2
- ADAMTS1 | c.*1013G>A | 3'UTR (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- AHSA1 | c.*185del | 3'UTR (DEL) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- C21orf91 | c.*2886_*2901del | 3'UTR (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- CACNG7 | chr19:53943723 G>A | 3'Flank (SNP) | VAF 15/54 reads (28%) | catalogued as rs563570781; called by muse, mutect2, varscan2
- CCAR1 | c.*537G>A | 3'UTR (SNP) | VAF 22/35 reads (63%) | called by muse, mutect2, varscan2
- CHURC1 | c.*1702A>G | 3'UTR (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- CNTRL | c.3964-16T>C | Intron (SNP) | VAF 76/538 reads (14%) | catalogued as rs548794609, COSV53043096, COSV53044199; called by muse, mutect2, varscan2
- CORO2A | c.*1137C>T | 3'UTR (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- CTAGE1 | c.*857C>A | 3'UTR (SNP) | VAF 122/366 reads (33%) | catalogued as rs906968302; called by muse, mutect2, varscan2
- CTBP1 | c.*354T>G | 3'UTR (SNP) | VAF 39/82 reads (48%) | catalogued as rs923017738; called by muse, mutect2, varscan2
- DYNC2I1 | c.*201C>T | 3'UTR (SNP) | VAF 79/116 reads (68%) | called by muse, mutect2, varscan2
- E2F2 | c.*1887G>C | 3'UTR (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- EIF1AX | c.*3163C>T | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- EIF5AL1 | c.*289del | 3'UTR (DEL) | VAF 28/57 reads (49%) | called by mutect2, pindel*, varscan2
- FAAH | c.785+79G>A | Intron (SNP) | VAF 5/50 reads (10%) | catalogued as rs1053622763; called by muse, mutect2, varscan2
- FAM117B | c.*3924C>A | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- FANCB | c.*45C>T | 3'UTR (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- FER1L4 | n.3642T>C | RNA (SNP) | VAF 78/214 reads (36%) | catalogued as rs746909698; called by muse, mutect2, varscan2
- G3BP1 | c.351+918A>G | Intron (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- GABRB3 | chr15:26773671 C>T | 5'Flank (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- GABRG1 | c.*4444T>C | 3'UTR (SNP) | VAF 78/211 reads (37%) | called by muse, mutect2, varscan2
- GGA2 | c.-44G>A | 5'UTR (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- GTF2A2 | c.*312A>C | 3'UTR (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- GTF2A2 | c.*123A>G | 3'UTR (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- HUWE1 | c.*25G>T | 3'UTR (SNP) | VAF 106/256 reads (41%) | catalogued as rs781977893, COSV53355016; called by muse, mutect2, varscan2
- ICE2 | c.*2264A>C | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- IGHJ6 | chr14:105863423 T>G | 5'Flank (SNP) | VAF 14/26 reads (54%) | called by muse, varscan2
- IGHJ6 | chr14:105863448 G>T | 5'Flank (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- IYD | c.688-1465C>T | Intron (SNP) | VAF 50/113 reads (44%) | catalogued as rs1279977278; called by muse, mutect2, varscan2
- KIFC3 | chr16:57802987 G>A | 5'Flank (SNP) | VAF 69/202 reads (34%) | catalogued as rs1555626095; called by muse, mutect2, varscan2
- KLK2 | c.494-32C>T | Intron (SNP) | VAF 89/274 reads (32%) | catalogued as rs750838733; called by muse, mutect2, varscan2
- MAT2B | chr5:163503320 G>A | 5'Flank (SNP) | VAF 207/657 reads (32%) | called by muse, mutect2, varscan2
- MCMDC2 | c.1073+353T>C | Intron (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- MYO10 | c.279+2850dup | Intron (INS) | VAF 18/69 reads (26%) | called by mutect2, varscan2
- NALCN | c.5023+184G>A | Intron (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- NEDD4 | c.*1657T>C | 3'UTR (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- NRDC | c.1643+116T>C | Intron (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- ONECUT3 | c.*4833G>A | 3'UTR (SNP) | VAF 39/167 reads (23%) | called by muse, mutect2, varscan2
- PACS1 | c.1375-164T>C | Intron (SNP) | VAF 138/221 reads (62%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.1524+548G>T | Intron (SNP) | VAF 57/137 reads (42%) | called by muse, mutect2, varscan2
- PRRC2B | c.*483G>T | 3'UTR (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2, varscan2
- RCC1 | c.-153+147C>T | Intron (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- RGS5 | c.*973C>T | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- RIC3 | c.*509G>T | 3'UTR (SNP) | VAF 52/154 reads (34%) | called by muse, mutect2, varscan2
- RNF175 | c.*177C>T | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- RPS10 | c.*613A>T | 3'UTR (SNP) | VAF 121/425 reads (28%) | called by muse, mutect2, varscan2
- RSU1 | c.*2700C>A | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- SATB1 | c.*624A>T | 3'UTR (SNP) | VAF 46/139 reads (33%) | catalogued as rs866520205, COSV100113511; called by muse, mutect2, varscan2
- SBK1 | c.*189C>T | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- SDHAF2 | c.37-746A>G | Intron (SNP) | VAF 19/74 reads (26%) | catalogued as rs962838505; called by muse, mutect2, varscan2
- SLC17A4 | c.*582C>T | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- SLC35A3 | chr1:100026264 del ATT | 3'Flank (DEL) | VAF 12/67 reads (18%) | catalogued as rs1557853262; called by mutect2, pindel, varscan2
- SLITRK4 | chrX:143626554 A>C | 3'Flank (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- SORCS1 | c.3372-63G>A | Intron (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- SOX30 | c.*599T>G | 3'UTR (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- SP3 | c.-272T>C | 5'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- ST6GALNAC6 | c.*1078T>C | 3'UTR (SNP) | VAF 32/276 reads (12%) | called by muse, mutect2, varscan2
- STARD4 | c.*249G>C | 3'UTR (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- SUPT3H | c.*753A>G | 3'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- TUBA1A | c.-277_-267del | 5'UTR (DEL) | VAF 25/231 reads (11%) | called by mutect2, pindel
- TXNDC5 | c.*804_*833del | 3'UTR (DEL) | VAF 32/195 reads (16%) | called by mutect2, pindel
- TXNDC5 | c.*142_*145del | 3'UTR (DEL) | VAF 36/131 reads (27%) | called by mutect2, varscan2
- USP48 | c.1450+137T>A | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+1605C>A | Intron (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
